FM case AD6123 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/2c196ab2-b6e1-4803-a712-f83fb4415ebf

Male, 42.1 years: Carcinoma, NOS (ICD-O-3 8010/3); specimen biopsied or resected from the urethra. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
